Surgical pathology report (de-identified scan), TCGA case TCGA-VR-AA4D, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-AA4D-01A (Primary Tumor).

ICD-3
Adenocarcinoma NOS 8140/3
Site - Esophagus, distal Hnd C15.5
2013/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Esophagus (Distal)

1-"Product of esophagogastrrectomy":

Moderately differentiated adenocarcinoma with papillary areas infiltrative up to submucosa.

Presence of lymphatic invasion.

Perineural infiltration not detected.

Infiltrative growth pattern.

Absence of necrosis.

Discrete peritumoral inflammatory infiltrate.

Surgical margins free of neoplastic compromise.

2-"Lymphadenectomy according to standardization":

Metastatic adenocarcinoma in 6 of 25 identified lymph nodes (6/25), with no capsular compromise, distributed as follows:

1/2 right cardiac; 2/7 left cardiac, 0/13 lesser curvature; 3/3 left gastric artery;

0/0 celiac trunk; 0/0 inferior para-esophageal.

3- "Greater omentum":

Free of neoplastic compromise.

4-"Esophageal margin":

Free of neoplastic compromise.

Source: NCI Genomic Data Commons file 0077ff5b-55d3-4dca-80c0-fe5527b77362 (TCGA-VR-AA4D.5A59F9F1-9F37-468D-B120-B12C92E2C474.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).